Somatic mutation profile of tumor specimen TCGA-13-0891-01A (aliquot TCGA-13-0891-01A-01W-0420-08) from TCGA case TCGA-13-0891, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: G3; Age at diagnosis: 73.6 years (26,886 days).
Specimen TCGA-13-0891-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ef88fb7a-8a52-4c76-85e3-33db6e461192.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-13-0891-10A (Blood Derived Normal), aliquot TCGA-13-0891-10A-01D-0399-01; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6329f035-6c9a-41e2-9ebc-a28c8b920c1e

The open-access MAF lists 38 somatic variants for this specimen: 31 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 6, Frame Shift Ins 2, Frame Shift Del 2, In Frame Del 2, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.659A>G p.Y220C | Missense Mutation (SNP) | VAF 369/416 reads (89%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912666, CM015378, CM951227, COSV52661282, COSV52677517; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ANK3 | c.6581C>G p.P2194R | Missense Mutation (SNP) | VAF 71/276 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.12); catalogued as rs1176168259, COSV55064235; called by muse, mutect2, varscan2
- ATP2A1 | c.649G>A p.G217S | Missense Mutation (SNP) | VAF 62/225 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs763205557; called by muse, mutect2, varscan2
- CCAR1 | c.410C>G p.S137C | Missense Mutation (SNP) | VAF 178/406 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV56270967; called by muse, mutect2, varscan2
- CLEC1A | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 43/375 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as rs1385478606, COSV59531103; called by muse, mutect2, varscan2
- CTIF | c.1691G>A p.R564Q | Missense Mutation (SNP) | VAF 47/193 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.962); catalogued as rs369410150; called by muse, mutect2, varscan2
- ERRFI1 | c.559A>G p.T187A | Missense Mutation (SNP) | VAF 211/399 reads (53%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs141040294; called by muse, mutect2, varscan2
- GRIN2C | c.2350G>A p.G784R | Missense Mutation (SNP) | VAF 47/139 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs866984765, COSV53114449; called by muse, mutect2, varscan2
- IGSF10 | c.2353C>G p.Q785E | Missense Mutation (SNP) | VAF 113/249 reads (45%) | SIFT tolerated (0.33); PolyPhen benign (0.015); catalogued as COSV56786128; called by muse, mutect2, varscan2
- ING4 | c.316C>T p.R106C | Missense Mutation (SNP) | VAF 62/416 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100444253, COSV58555399; called by muse, mutect2, varscan2
- LRIG2 | c.225dup p.D76Rfs*10 | Frame Shift Ins (INS) | VAF 4/28 reads (14%) | catalogued as rs768751013; called by pindel, varscan2
- MAB21L1 | c.428G>A p.C143Y | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.744); catalogued as COSV59795399; called by muse, mutect2, varscan2
- MAP2K3 | c.244C>T p.R82W (on ENST00000342679 / NM_145109.3; = p.R53W on NM_002756.4) | Missense Mutation (SNP) | VAF 20/31 reads (65%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.94); catalogued as rs766095224, COSV57570102; called by muse, mutect2
- NLRP3 | c.1954G>A p.E652K | Missense Mutation (SNP) | VAF 56/1347 reads (4%) | SIFT tolerated (0.81); PolyPhen benign (0.053); catalogued as rs768966147, COSV60222235; called by muse, mutect2
- NUMA1 | c.1324G>A p.E442K | Missense Mutation (SNP) | VAF 25/154 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as rs1303395091, COSV61187016; called by muse, mutect2, varscan2
- OPN4 | c.602G>A p.W201* | Nonsense Mutation (SNP) | VAF 60/107 reads (56%) | catalogued as COSV54117156; called by muse, mutect2, varscan2
- PINX1 | c.921G>T p.E307D | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.411); catalogued as COSV100134698; called by muse, mutect2
- PPARGC1A | c.2390G>A p.R797H | Missense Mutation (SNP) | VAF 197/517 reads (38%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.98); catalogued as rs200187877; called by muse, mutect2, varscan2
- PRDM2 | c.4027G>A p.D1343N | Missense Mutation (SNP) | VAF 52/1144 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99341011; called by muse, mutect2
- SH3PXD2A | c.328dup p.H110Pfs*6 | Frame Shift Ins (INS) | VAF 16/75 reads (21%) | catalogued as rs777796332; called by mutect2, varscan2
- THRAP3 | c.745C>G p.P249A | Missense Mutation (SNP) | VAF 62/344 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV63568508; called by muse, mutect2, varscan2
- TMEM94 | c.1249G>A p.D417N | Missense Mutation (SNP) | VAF 148/266 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs371200932; called by muse, varscan2
- UNC5C | c.529G>A p.E177K | Missense Mutation (SNP) | VAF 22/156 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.396); catalogued as COSV101498014, COSV71660622; called by muse, mutect2, varscan2
- ZBTB34 | c.447C>A p.N149K | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.983); catalogued as COSV59860120; called by muse, mutect2, varscan2
- ZNF133 | c.1418G>T p.R473L (on ENST00000316358 / NM_001352454.2; = p.R472L on NM_003434.7 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 56/376 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100315454; called by muse, varscan2
- ZNF3 | c.1105G>A p.E369K | Missense Mutation (SNP) | VAF 121/262 reads (46%) | SIFT tolerated (0.42); PolyPhen benign (0.403); catalogued as rs1023341106, COSV52795343; called by muse, mutect2, varscan2
- CDK12 | c.3041_3049del p.T1014_Q1016del | In Frame Del (DEL) | VAF 326/481 reads (68%) | called by mutect2, pindel, varscan2
- CPS1 | c.1059del p.F353Lfs*2 | Frame Shift Del (DEL) | VAF 74/141 reads (52%) | called by mutect2, pindel, varscan2
- DNAH3 | c.8300_8302del p.L2767_E2768delinsQ | In Frame Del (DEL) | VAF 1071/1622 reads (66%) | called by pindel, varscan2
- NIN | c.4448_4452del p.S1483Wfs*13 | Frame Shift Del (DEL) | VAF 92/367 reads (25%) | called by mutect2, pindel, varscan2
- PSMG3 | c.298G>C p.A100P | Missense Mutation (SNP) | VAF 40/218 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by mutect2, varscan2
- EVI5L | c.180C>T p.G60= | Silent (SNP) | VAF 11/25 reads (44%) | catalogued as rs373550043; called by muse, mutect2, varscan2
- GNL1 | c.750C>T p.H250= | Silent (SNP) | VAF 92/309 reads (30%) | catalogued as rs150038929; called by muse, mutect2, varscan2
- KNTC1 | c.5076C>T p.I1692= | Silent (SNP) | VAF 19/55 reads (35%) | catalogued as COSV61081185; called by muse, mutect2, varscan2
- OR4K5 | c.291C>T p.C97= | Silent (SNP) | VAF 244/1149 reads (21%) | catalogued as COSV60003976; called by muse, mutect2, varscan2
- PCARE | c.840G>T p.V280= | Silent (SNP) | VAF 13/140 reads (9%) | catalogued as COSV100527197, COSV59055578; called by muse, mutect2
- PKD1L2 | c.135C>T p.L45= | Silent (SNP) | VAF 154/544 reads (28%) | catalogued as rs529919593, COSV61416415; called by muse, mutect2, varscan2
- ATP6V1G3 | c.82+3883T>A | Intron (SNP) | VAF 807/1396 reads (58%) | catalogued as COSV99810718; called by muse, mutect2, varscan2
